Somatic mutation profile of tumor specimen 0DSWA0 from CCDI case PBCING, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.9 years (6,545 days).
Specimen 0DSWA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4c0dc37-fb8e-46fb-9a03-cd35598b2661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3114ca51-94e5-4de8-801a-95778ae21376

The open-access MAF lists 43 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 4, 3'Flank 2, 3'UTR 2, Nonsense Mutation 2, 5'UTR 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 59/548 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS9 | c.4141G>A p.G1381S | Missense Mutation (SNP) | VAF 77/439 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs1453748563; called by muse, mutect2, varscan2
- ATP2B3 | c.3431C>G p.T1144R | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV54857474; called by muse, mutect2, varscan2
- CSMD1 | c.1222C>T p.R408* (on ENST00000520002; = p.R407* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 94/384 reads (24%) | catalogued as rs376057777, COSV68211442; called by mutect2, varscan2
- FBXL7 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.436); catalogued as rs780242293; called by muse, varscan2
- GNAS | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs772710903, COSV58341899; called by mutect2, varscan2
- LONRF3 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100504803; called by muse, mutect2, varscan2
- NBEAL2 | c.2914G>T p.V972L | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99438156; called by muse, mutect2, varscan2
- NUP58 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1217623977; called by muse, mutect2, varscan2
- PCDHB11 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs782535816, COSV61310815; called by muse, mutect2, varscan2
- SLC7A6 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1262376017, COSV54719637; called by muse, mutect2, varscan2
- SPTBN5 | c.5803C>T p.R1935C | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs552947313; called by muse, mutect2, varscan2
- CCDC121 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 155/322 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CTNNB1 | c.111_116del p.G38_A39del | In Frame Del (DEL) | VAF 48/322 reads (15%) | called by mutect2, varscan2
- DNAL1 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 19/510 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- FRAS1 | c.1412A>T p.Q471L | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- HDAC9 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- HEG1 | c.3193+5G>T | Splice Region (SNP) | VAF 71/363 reads (20%) | called by muse, mutect2, varscan2
- HTRA4 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 46/216 reads (21%) | called by muse, mutect2, varscan2
- IRX2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ITIH6 | c.104T>G p.L35W | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- NLRC3 | c.169T>G p.C57G | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- PDGFRL | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SHISA6 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SLC12A5 | c.1027C>A p.L343I (on ENST00000454036 / NM_001134771.2; = p.L320I on NM_020708.5) | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2
- CPSF1 | c.3696G>C p.S1232= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as COSV58235209; called by muse, mutect2, varscan2
- ERI2 | c.1197G>T p.L399= | Silent (SNP) | VAF 21/453 reads (5%) | called by muse, mutect2
- ERICH5 | c.129A>G p.A43= | Silent (SNP) | VAF 69/370 reads (19%) | catalogued as rs1386823975; called by muse, mutect2, varscan2
- KRT2 | c.969G>A p.Q323= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- NIPAL4 | c.69G>A p.P23= | Silent (SNP) | VAF 13/94 reads (14%) | called by mutect2, varscan2
- OR2Y1 | c.147C>A p.S49= | Silent (SNP) | VAF 47/170 reads (28%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.1269C>T p.A423= (on ENST00000295902; = p.A367= on NM_198859.4) | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs755732268, COSV99898268; called by muse, mutect2, varscan2
- SVEP1 | c.1893C>A p.G631= | Silent (SNP) | VAF 88/330 reads (27%) | called by muse, mutect2, varscan2
- BASP1 | c.*63C>A | 3'UTR (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100493793; called by muse, varscan2
- CTU1 | c.-14C>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- DOK5 | c.*47A>G | 3'UTR (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- EEF1D | c.-7-2357G>A | Intron (SNP) | VAF 28/151 reads (19%) | called by mutect2, varscan2
- EXOC7 | c.1054+21C>T | Intron (SNP) | VAF 19/85 reads (22%) | catalogued as rs771594941; called by mutect2, varscan2
- OR10Z1 | chr1:158608266 T>G | 3'Flank (SNP) | VAF 45/176 reads (26%) | catalogued as COSV63526763; called by muse, mutect2, varscan2
- PTEN | c.-366_-363del | 5'UTR (DEL) | VAF 4/32 reads (13%) | catalogued as rs1365232630; called by mutect2, varscan2
- RIMS2 | c.698+52994G>A | Intron (SNP) | VAF 21/594 reads (4%) | called by muse, mutect2
- SMTN | c.2089+42G>A | Intron (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- ZNF738 | chr19:21382995 G>T | 3'Flank (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
